FM case AD6134 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/b86ba937-cee5-40cb-8c12-66d669bf7a48

Female, 51.5 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the specified parts of peritoneum. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Tumor.
